EXCEPTIONAL_RESPONDERS case ER-B041 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Anus and anal canal. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/579b832c-cc1f-4fa4-b4b8-f253161b93f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (1)
1. Spindle cell carcinoma, NOS: ICD-O-3 morphology code: 8004/3; Tissue or organ of origin: Anal canal; Site of resection or biopsy: Anal canal; Classification of tumor: metastasis; Age at diagnosis: 59.4 years (21,683 days); Year of diagnosis: 2010; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Days to last follow up: 2,373 days (6.5 years); Days to best overall response: 1,087 days (3.0 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 1,017 days (2.8 years); Days to treatment end: 2,382 days (6.5 years).

Follow-up (1 entry)
- Days to follow up: 2,373 days (6.5 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 2,373 days (6.5 years); Days to recurrence: 978 days (2.7 years); Days progression-free: 2,254 days (6.2 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B041-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-B041-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 10; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
